CCDI case PBBRKD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/39d75f2c-7e3d-471a-bbb8-1c2af068f975

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.4 years (151 days).

Biospecimens (3 samples)
- Sample 0DFSQG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFSS6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFUJM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
